Somatic mutation profile of tumor specimen TCGA-06-0745-01A (aliquot TCGA-06-0745-01A-01D-1492-08) from TCGA case TCGA-06-0745, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.9 years (21,884 days).
Specimen TCGA-06-0745-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc2d6698-a719-4757-b4c7-ace26ce6fbb3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0745-10A (Blood Derived Normal), aliquot TCGA-06-0745-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a06e4fa4-9887-4a0c-acab-99b0aa63794e

The open-access MAF lists 56 somatic variants for this specimen: 41 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 11, Nonsense Mutation 4, Intron 2, Splice Site 2, RNA 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.787A>T p.T263S | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as COSV55946003; called by muse, mutect2
- ADGRV1 | c.6328A>G p.I2110V | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.557); catalogued as COSV67979440; called by muse, mutect2, varscan2
- AKAP6 | c.3652G>C p.E1218Q | Missense Mutation (SNP) | VAF 54/80 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55206236, COSV55210771; called by muse, mutect2, varscan2
- ART1 | c.727A>T p.I243F | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51703064; called by muse, mutect2, varscan2
- ATE1 | c.170+2del p.X57_splice | Splice Site (DEL) | VAF 46/86 reads (53%) | catalogued as COSV56443113; called by mutect2, pindel, varscan2
- C8orf34 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 22/48 reads (46%) | catalogued as rs748338743, COSV100447456, COSV61372204; called by muse, mutect2, varscan2
- CHD9 | c.480T>A p.H160Q | Missense Mutation (SNP) | VAF 70/144 reads (49%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV68297211; called by muse, mutect2, varscan2
- CHM | c.633G>T p.K211N | Missense Mutation (SNP) | VAF 83/98 reads (85%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV63300047; called by muse, mutect2, varscan2
- CIITA | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs376464815; called by muse, mutect2
- CTU2 | c.682C>A p.L228M | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs774592158, COSV56333852; called by muse, mutect2, varscan2
- DISP3 | c.4162G>T p.A1388S | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs533939192, COSV53821519; called by muse, mutect2, varscan2
- DLD | c.1090C>T p.H364Y | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52737006; called by muse, mutect2, varscan2
- EGR2 | c.332G>C p.G111A | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV54346288; called by muse, mutect2, varscan2
- FSTL1 | c.694+1G>A p.X232_splice | Splice Site (SNP) | VAF 32/82 reads (39%) | catalogued as COSV55232215; called by muse, mutect2, varscan2
- GTF3C1 | c.4408G>C p.E1470Q | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.074); catalogued as COSV62239239, COSV62244043; called by muse, mutect2, varscan2
- ITGB4 | c.2020C>T p.R674W | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1191842048, COSV52322406; called by muse, mutect2, varscan2
- KCNC2 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.013); catalogued as rs1209434610, COSV54363607; called by muse, varscan2
- MAST4 | c.1715C>T p.T572M (on ENST00000403625 / NM_001164664.2; = p.T383M on NM_015183.3) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs367779827; called by muse, mutect2, varscan2
- MRM2 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.001); catalogued as rs768327953, COSV54247619; called by muse, mutect2, varscan2
- MUC16 | c.15257G>A p.R5086H | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.193); catalogued as rs533387298, COSV67442388, COSV67493775; called by muse, mutect2, varscan2
- MXRA5 | c.3839G>A p.R1280K | Missense Mutation (SNP) | VAF 81/106 reads (76%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV54225421, COSV99478129; called by muse, mutect2, varscan2
- MYCBP2 | c.1597T>C p.W533R (on ENST00000357337; = p.W571R on NM_015057.5) | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV62011412; called by muse, mutect2, varscan2
- MYT1L | c.3127G>A p.G1043R | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs774591482, COSV67701199; called by muse, mutect2, varscan2
- OR4D5 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 90/210 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as rs564572858, COSV58305578; called by muse, mutect2, varscan2
- OR5K4 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 177/282 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201188789; called by muse, mutect2, varscan2
- PCDHB13 | c.1904C>T p.A635V | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.034); catalogued as rs782557994, COSV53393643; called by muse, mutect2, varscan2
- PCDHB3 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 115/266 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV50564677, COSV50581609; called by muse, mutect2, varscan2
- PPP4R3A | c.1627C>G p.L543V (on ENST00000554943 / NM_001366432.1; = p.L530V on NM_001284280.1) | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.685); catalogued as COSV61503633; called by muse, mutect2, varscan2
- QRFP | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV58064728; called by muse, mutect2, varscan2
- RB1CC1 | c.1565A>G p.K522R | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs766968433, COSV50243445; called by muse, mutect2, varscan2
- RGL4 | c.1279G>T p.E427* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as COSV51943249; called by muse, mutect2, varscan2
- SBF1 | c.1864G>C p.D622H | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62366031; called by muse, mutect2, varscan2
- SEC31A | c.1291C>T p.Q431* | Nonsense Mutation (SNP) | VAF 29/83 reads (35%) | catalogued as COSV52341986; called by muse, mutect2, varscan2
- SLC17A9 | c.970G>A p.V324I | Missense Mutation (SNP) | VAF 160/656 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.021); catalogued as rs772910639, COSV64846708; called by muse, varscan2
- SMYD3 | c.876A>C p.K292N (on ENST00000490107 / NM_001375962.1; = p.K233N on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV63625800; called by muse, mutect2, varscan2
- SNX9 | c.960A>T p.E320D | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as COSV67583345; called by muse, mutect2, varscan2
- TRPM1 | c.4649C>A p.S1550* | Nonsense Mutation (SNP) | VAF 105/151 reads (70%) | catalogued as COSV56631160; called by muse, mutect2, varscan2
- ZNF813 | c.1675G>A p.V559I | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as COSV67175888; called by muse, mutect2, varscan2
- BCL2 | c.104_106del p.V35del | In Frame Del (DEL) | VAF 31/101 reads (31%) | called by mutect2, pindel, varscan2
- DOCK5 | c.2444C>A p.A815E | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- IGHV1-45 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); called by muse, varscan2
- AHNAK | c.3156C>T p.G1052= | Silent (SNP) | VAF 80/176 reads (45%) | catalogued as COSV57205158; called by muse, mutect2, varscan2
- C3 | c.651C>G p.V217= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as COSV55569560; called by muse, mutect2, varscan2
- CHEK2 | c.192G>A p.E64= | Silent (SNP) | VAF 63/150 reads (42%) | catalogued as COSV60416501; called by muse, mutect2, varscan2
- COL28A1 | c.2655C>T p.N885= | Silent (SNP) | VAF 38/160 reads (24%) | catalogued as rs368864863; called by muse, mutect2, varscan2
- CSN1S1 | c.480T>C p.P160= | Silent (SNP) | VAF 124/281 reads (44%) | catalogued as COSV55889878, COSV99886693; called by muse, mutect2, varscan2
- FAM120A | c.1743C>A p.I581= | Silent (SNP) | VAF 32/121 reads (26%) | catalogued as COSV52901716; called by muse, mutect2, varscan2
- KIF18A | c.2151G>A p.P717= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs575102434, COSV54181447, COSV54184532; called by muse, mutect2, varscan2
- LCT | c.2079C>T p.N693= | Silent (SNP) | VAF 54/152 reads (36%) | catalogued as rs767194078, COSV51544826; called by muse, mutect2, varscan2
- PCDH11X | c.228A>T p.R76= | Silent (SNP) | VAF 104/132 reads (79%) | catalogued as COSV53446317; called by muse, mutect2, varscan2
- RYR2 | c.12996C>G p.A4332= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as COSV63665871; called by muse, mutect2, varscan2
- TFEC | c.585A>G p.E195= | Silent (SNP) | VAF 24/211 reads (11%) | catalogued as COSV55397980; called by muse, mutect2, varscan2
- CHEK2 | c.-1G>C | 5'UTR (SNP) | VAF 25/76 reads (33%) | catalogued as COSV60426160; called by muse, mutect2, varscan2
- DNM1P46 | n.512G>A | RNA (SNP) | VAF 10/22 reads (45%) | catalogued as rs376517074; called by muse, mutect2, varscan2
- RMDN2 | c.453-21997A>T | Intron (SNP) | VAF 48/115 reads (42%) | catalogued as COSV52229611; called by muse, mutect2, varscan2
- THRA | c.1110+102C>A | Intron (SNP) | VAF 34/84 reads (40%) | catalogued as COSV52846199; called by muse, mutect2, varscan2
